Somatic mutation profile of tumor specimen 0DT9NT from CCDI case PBCJLL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,269 days).
Specimen 0DT9NT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a1d3124-671e-42c4-9978-21de8d5bb207.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9NH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03ed42da-76bb-4648-8e14-023a5c7e1bdf

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/393 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CRYBG3 | c.4514A>G p.E1505G | Missense Mutation (SNP) | VAF 52/740 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2
- FAM71C | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 30/708 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- RIPOR2 | c.2789A>C p.D930A | Missense Mutation (SNP) | VAF 21/554 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.009); called by muse, mutect2
- ZC3H18 | c.1068G>A p.P356= | Silent (SNP) | VAF 41/473 reads (9%) | catalogued as rs763558624; called by muse, mutect2
